Surgical pathology report (de-identified scan), TCGA case TCGA-B0-5110, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-B0-5110-01A (Primary Tumor).

FINAL DIAGNOSIS

RIGHT KIDNEY, LOWER POLE, PARTIAL NEPHRECTOMY –

- A. RENAL CELL CARCINOMA, CONVENTIONAL (CLEAR CELL) TYPE.
- B. FUHRMAN NUCLEAR GRADE IS 2 OF 4.
- C. MAXIMAL TUMOR DIAMETER IS 3.0 CM.
- D. CARCINOMA IS CONFINED TO THE KIDNEY, WITHOUT EXTRACAPSULAR EXTENSION.
- E. NO ANGIOLYMPHATIC INVASION IS IDENTIFIED.
- F. ALL ASSESSABLE SURGICAL RESECTION MARGINS ARE FREE OF THE NEOPLASM (See Comment).
- G. NON-NEOPLASTIC KIDNEY (WHICH IS ADJACENT TO THE TUMOR) SHOWS MODERATE ARTERIAL /
ARTERIOLAR SCLEROSIS AND MODERATE GLOBAL GLOMERULOSCLEROSIS, WITH WELL-PRESERVED
TUBULES AND INTERSTITIUM.
- H. TNM PATHOLOGIC STAGE: pT1a NX MX (See Synoptic).

Source: NCI Genomic Data Commons file 5bb4daa3-c0d2-4817-84fc-c5a133c1a092 (TCGA-B0-5110.B0AFD2B8-18EA-499F-AA35-96200644B478.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).